Somatic mutation profile of tumor specimen TCGA-PA-A5YG-01A (aliquot TCGA-PA-A5YG-01A-11D-A29I-10) from TCGA case TCGA-PA-A5YG, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 51.8 years (18,926 days).
Specimen TCGA-PA-A5YG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07ae7d83-798a-4445-b7b5-e7f1f0c78e4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PA-A5YG-10A (Blood Derived Normal), aliquot TCGA-PA-A5YG-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a728b68-b9f3-4fc3-877f-7e9757a19ab2

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRT12 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as rs763384010, COSV52430375, COSV52430961; called by muse, mutect2, varscan2
- SEZ6L2 | c.2173G>A p.V725I (on ENST00000308713 / NM_001114099.3; = p.V655I on NM_012410.4) | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs146085461, COSV100435497; called by muse, varscan2
- ST6GAL2 | c.1479G>T p.Q493H | Missense Mutation (SNP) | VAF 27/145 reads (19%) | PolyPhen possibly damaging (0.593); catalogued as COSV62416607; called by muse, mutect2, varscan2
- DIP2B | c.950A>G p.E317G | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NCOA1 | c.2861C>T p.A954V | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMTN | c.2464C>T p.Q822* | Nonsense Mutation (SNP) | VAF 7/146 reads (5%) | called by muse, mutect2
- WSCD2 | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 70/313 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- TMPRSS6 | c.2268G>A p.P756= | Silent (SNP) | VAF 43/171 reads (25%) | catalogued as rs773403505; called by muse, mutect2, varscan2
